Gene-level copy-number profile of tumor specimen ALCH-B2TZ-TTP1-A from ALCHEMIST case ALCH-B2TZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.9 years (25,181 days).
Specimen ALCH-B2TZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3de7978-a9fd-4ca7-9fe9-f94d4f492c91.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2TZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/e5c49adb-b546-48fb-9ead-cf42cb0820cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 544; copy number 1: 4,952; copy number 2: 47,129; copy number 3: 5,612; copy number 4: 452; copy number 5: 160; copy number 6: 26; copy number 7: 17; copy number 8: 2; copy number 9: 2; copy number 14: 1; copy number 21: 2; copy number 37: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–2): PRSS46P.
- chr4:1,550,284–1,550,572, 1 gene: AC147067.2.
- chr7:100,868,036–100,868,107, 1 gene (within-gene range 0–3): MIR6875.
- chr9:130,664,594–130,682,986, 1 gene: PRDM12.
- chr11:61,513,714–61,581,148, 3 genes: SYT7, AP003108.5, AP003559.1.
- chr12:132,618,776–132,622,973, 2 genes: P2RX2, AC131212.4.
- chr15:25,184,306–25,184,387, 1 gene (within-gene range 0–1): SNORD115-8.
- chr15:25,209,918–25,225,284, 9 genes (within-gene range 0–1): SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–2): AC018445.3.
- chr19:1,905,372–1,926,013, 2 genes (within-gene range 0–2): SCAMP4, ADAT3.
- chr19:6,494,319–6,502,848, 3 genes: TUBB4A, AC010503.2, AC010503.1.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.
- chr21:43,092,956–43,107,570, 1 gene: U2AF1.
- chr22:38,130,216–38,150,612, 1 gene (within-gene range 0–2): AL022322.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 211 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,183,006–204,196,491, 2 genes, copy number 7: AL592114.2, KISS1.
- chr6:29,887,294–29,888,268, 1 gene, copy number 8 (within-gene range 4–8): AL645929.1.
- chr6:29,934,101–29,934,286, 1 gene, copy number 5: HLA-U.
- chr8:126,474,189–133,326,404, 83 genes, copy number 5–7 (broad region; genes not listed).
- chr8:142,785,374–142,812,120, 2 genes, copy number 5 (within-gene range 1–5): AC083841.2, AC083841.4.
- chr14:105,583,731–105,588,395, 1 gene, copy number 5: IGHA2.
- chr19:34,172,504–35,813,299, 108 genes, copy number 5 (broad region; genes not listed).
- chr21:43,140,523–43,141,092, 1 gene, copy number 8: FRGCA.
- chr21:43,169,008–43,172,805, 1 gene, copy number 14: CRYAA.
- chr21:43,446,601–43,479,534, 2 genes, copy number 9–37 (within-gene range 1–37): LINC00319, LINC00313.
- chr21:44,133,610–44,210,114, 4 genes, copy number 5–21 (within-gene range 2–21): GATD3A, LINC01678, AP001056.2, AP001056.1.
- chr22:18,636,445–18,638,405, 1 gene, copy number 9: CA15P2.
- chr22:18,733,914–18,843,399, 4 genes, copy number 5–6 (within-gene range 5–7): FAM230E, GGT3P, AC008132.2, E2F6P1.

Autosomal genes at a single copy (total copy number 1): 2,622. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
